Surgical pathology report (de-identified scan), TCGA case TCGA-08-0359, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0359-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, left occipital, biopsy: Glioblastoma multiforme, WHO grade IV.
- B. Brain, left occipital, biopsy: Glioblastoma multiforme, WHO grade IV.
-

Intraoperative Diagnosis

FS1 (A) Brain, left occipital tumor, biopsy: WHO glioblastoma multiforme, grade IV. Tissue section and cytologic preparation.

Gross Description

The specimen is received fresh in two parts, each labeled with the patient's name and medical record number.

Part A is additionally labeled "left occipital tumor." It consists of a single irregular, unoriented fragment of tan-red, gelatinous, soft tissue, measuring 0.8 x 0.5 x 0.3 cm. A small portion of the specimen is used for cytological preparation as TP1. One-half of the specimen is submitted for frozen section diagnosis as FS1, with the frozen section remnant submitted in cassette A1. The remaining half of the specimen is submitted in cassette A2.

Part B is additionally labeled "tumor." It consists of a portion of brain tissue and tumor, measuring 8.5 x 7.0 x 3.2 cm. Extensive areas of necrosis are identified. Representative sections of the tumor and the brain-tumor interface are submitted in cassettes B1 through B9, with cassette B10 containing uninvolved brain.

Clinical History

The patient is a year-old woman with a left occipital tumor, suspicious for glioblastoma multiforme.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file 8506c1c9-616f-4b70-a7f3-fedcf58ea0ad (TCGA-08-0359.C95BD6B5-0C33-4567-AD43-352283E6377F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).